Surgical pathology report (de-identified scan), TCGA case TCGA-23-1119, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1119-01A (Primary Tumor).

[page 1 of 4]
SURGICAL P

PATIENT:

Hospital N

Date of Bi

Soc. Sec.

Location:

Pathologis

Assistant:

Attending

Ordering M

Copies To:

DIAGNOSIS:

- 1: UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES, RADICAL HYSTERECTOMY:
- Cervix with chronic cystic cervicitis and focal immature squamous metaplasia
- Uterine corpus with an endometrial polyp at the lower uterine segment; the lesion is composed of hyperplastic endometrial and endocervical glands in a fibrotic stroma
- Endometrium is atrophic with focal cystic change
- Uterine posterior serosa extensively infiltrated by high grade serous papillary adenocarcinoma
- Left ovary and fallopian tube with a high grade serous papillary carcinoma
- It replaces the left ovary, ruptures the ovarian surface and infiltrates the serosa
- Focal involvement, left fallopian tube
- Focal vascular and lymphatic invasion present
- Right ovary with focal infiltration of serosa and superficial cortex by high grade serous papillary carcinoma
- The tumor is focally present on the serosa of the right fallopian tube; paratubal cysts also present
- 2: BLADDER PERITONEUM:
- Fibroadipose tissue and peritoneum infiltrated by high grade serous papillary adenocarcinoma
- 3-5: OMENTUM NO.1, NO.2 AND NO.3:
- Portions of omentum with focal infiltration by high grade serous papillary carcinoma
- Focal chronic inflammation and mesothelial cell hyperplasia also present
- 6: CUL-DE-SAC TUMOR:
- Fibrous tissue infiltrated by high grade serous papillary carcinoma
- 7: SIGMOID TUMOR:
- Fibroadipose tissue infiltrated by high grade serous papillary carcinoma
- 8: LEFT SIGMOID TUMOR:
- Peritoneum and fibrous tissue infiltrated by high grade serous papillary carcinoma
- 9: DIAPHRAGM TUMOR:
- Peritoneum and fibroadipose tissue infiltrated by high grade

[page 2 of 4]
serous papillary carcinoma

10: LEFT SIDE WALL TUMOR:

-Fibroadipose tissue infiltrated by high grade serous papillary carcinoma

11: LEFT PELVIC LYMPH NODE:

-Two lymph nodes, negative for tumor

12: BLADDER TUMOR:

-Fibrous tissue infiltrated by high grade serous papillary carcinoma

HISTORY: Ovarian cancer

MICROSCOPIC:

See Diagnosis.

GROSS:

1: UTERUS, BILATERAL TUBES AND OVARIES

Labeled "uterus, bilateral tubes and ovaries", received fresh from Operating Room, a portion is taken sterilely for [REDACTED] and the remaining is subsequently placed in formalin is a 110 gram uterus with bilateral fallopian tubes and ovaries. The uterus measures 5.6 cm from fundus to ectocervix, 3 cm from cornu to cornu, and 2.5 cm from anterior to posterior. The anterior serosal surface is tan with multiple fibrous adhesions. On the posterior serosal surface of the uterus is a 4 x 3 x 1.5 cm tan nodular mass with a tan, firm cut surface. The ectocervix measures 3.5 x 3 cm and is lined by tan, smooth epithelium. The cervical os is patent and measures 0.7 x 0.4 cm. The uterus is opened anteriorly. The endocervical canal measures 2.2 cm and is lined by tan-white rugose epithelium. The endometrial cavity measures 3 x 1.5 cm and is lined by tan-red velvety epithelium ranging up to less than 0.1 cm. Present in the posterior lower uterine segment is a 0.5 x 0.4 x 0.2 cm soft, tan polypoid tissue. The myometrium measures up to 1.5 cm and is tan-white and fibrous. The left ovary is completely replaced by a tan, firm, irregular, solid mass measuring 9 x 7 x 3 cm. The external surface of the mass is tan, white, firm, irregular with scattered areas of congestion. The firm mass encroaches the isthmic portion of the fallopian tube and also the fimbriated end. Cut section through the mass reveals variegated soft, tan to firm yellow surface with scattered areas of congestion. No residual normal ovarian tissue is identified. The mass seems to extend to the posterior wall of the uterus. The attached fallopian tube measures 8 cm in length. The fimbriated end is obscured by the tan, firm mass. The mass encroaches on the isthmic portion of the fallopian tube. Cut section of the fallopian tube reveals a central stellate lumen surrounded by wall thickness ranging up to 0.2 cm. The right fallopian tube measures 6.5 cm in length with an identifiable fimbriated end. The serosal surface is pink-tan, smooth and glistening with scattered areas of congestion. Cut section reveals a central stellate lumen surrounded by wall thickness ranging up to 0.2 cm. There are multiple cysts filled with serous fluid present along the fallopian tube ranging from 0.1 to 0.4 cm in maximum thickness. The right ovary measures 3 x 1.5 x 0.6 cm. The external surface is tan-white and cerebriform. Cut section reveals a tan-white fibrous parenchyma. There is no gross evidence of tumor on the right ovary. Representative sections are submitted.

- A. Anterior cervix - 1
- B. Posterior cervix - 1
- C. Anterior endomyometrium - 2
- D. Posterior endomyometrium with polyp - 2

[page 3 of 4]
- E. Tumor on the posterior uterine wall - 1
- F. Right ovary, fallopian tube and paratubal cyst - 6
- G. Left fallopian tube - 3
- H. Tumor at the left fallopian tube (fimbriated end) - 2
- I-M. Tumor - 2 each

2: BLADDER PERITONEUM

Labeled "bladder peritoneum" and received in formalin are two fragments of soft, tan tissue admixed with yellow lobulated adipose tissue measuring 2 x 0.6 x 0.5 cm and 2.5 x 1 x 0.3 cm.

- N. All embedded - 2

3: OMENTUM NO.1

Labeled "omentum no. 1" and received in formalin is a 10.5 x 7 x 1 cm portion of yellow lobulated adipose tissue. No tumor is seen.

- O,P. Representative sections - Multiple each

4: OMENTUM NO.2

Labeled "omentum no. 2" and received in formalin is a 10.5 x 7 x 1 cm portion of yellow lobulated adipose tissue. There is no gross evidence of tumor. Representative sections are submitted.

- Q,R. Representative sections - Multiple each

5: OMENTUM NO.3

Labeled "omentum no. 3" and received in formalin is a 20 x 7 x 0.5 cm portion of yellow lobulated portion of yellow lobulated adipose tissue. No gross evidence of tumor.

- S,T. Representative sections - Multiple each

6: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin are multiple fragments of soft, tan tissue admixed with blood measuring in aggregate 4 x 2.5 x 1 cm and ranging from 0.5 to 2 cm in greatest dimension.

- U. Representative sections - Multiple

7: SIGMOID TUMOR

Labeled "sigmoid tumor" and received in formalin are multiple fragments of soft, tan tissue admixed with blood measuring in aggregate 4 x 3 x 1 cm and ranging from 0.6 to 2 cm in greatest dimension.

- V. Representative sections - Multiple

8: LEFT SIGMOID TUMOR

Labeled "left sigmoid tumor" and received in formalin are multiple fragments of soft, tan tissue measuring in aggregate to 3 x 3 x 1.5 cm and ranging from 0.5 to 2 cm in greatest dimension.

- W. Representative sections - Multiple

9: DIAPHRAGM TUMOR

Labeled "diaphragm tumor" and received in formalin are four fragments of soft, tan tissue measuring in aggregate 1.5 x 0.6 x 0.4 cm and ranging from 0.4 to 0.7 cm in greatest dimension.

- X. All embedded - Multiple

10: LEFT SIDE WALL TUMOR

Labeled "left side wall tumor" and received in formalin is a 3 x 2 x 0.8 cm fragment of soft, tan tissue with loosely adherent yellow lobulated adipose tissue.

[page 4 of 4]
Y. Representative sections - 4

11: LEFT PELVIC LYMPH NODE

Labeled "left pelvic lymph node" and received in formalin are two, soft, tan lymph nodes measuring 1 x 0.5 x 0.5 cm and 1.2 x 0.6 x 0.5 cm. Also received are portions of yellow lobulated adipose tissue aggregating to 1 x 0.5 x 0.2 cm. The specimen is all embedded.

Z. Two lymph nodes and adipose tissue - Multiple

12: BLADDER TUMOR

Labeled "bladder tumor" and received in formalin is a 1.5 x 1 x 0.5 cm fragment of soft, tan tissue. The specimen is serially sectioned and all embedded.

AA. 4

OPERATIVE CONSULT (GROSS):

Tumor, left ovary

Source: NCI Genomic Data Commons file 44bd4dcf-1e30-46d3-82b3-f88aaafbe068 (TCGA-23-1119.86389912-6945-49E6-9255-E7A41FDE197A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).